Somatic mutation profile of tumor specimen C3N-00320-01 (aliquot CPT0012360009) from CPTAC case C3N-00320, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 67.3 years (24,594 days).
Specimen C3N-00320-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17247f56-72fe-444f-82ff-d59e535cd1dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00320-31 (Blood Derived Normal), aliquot CPT0012530002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10d17f95-ae0c-4cd1-b9f0-ce9cf761486f

The open-access MAF lists 120 somatic variants for this specimen: 84 protein-altering or splice-affecting, 22 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 22, Intron 9, Frame Shift Del 8, Nonsense Mutation 5, In Frame Del 4, 3'UTR 3, 5'UTR 2, Frame Shift Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.4447T>C p.C1483R | Missense Mutation (SNP) | VAF 32/117 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs1057519914, COSV63875155; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NOTCH3 | c.213G>T p.W71C | Missense Mutation (SNP) | VAF 86/364 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs28937321, CM961042; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.340+2T>A p.X114_splice | Splice Site (SNP) | VAF 104/346 reads (30%) | hotspot (GDC flag); catalogued as CD983001, COSV56547957, COSV56551654, COSV56551713, COSV56563827; called by muse, mutect2, varscan2
- ADGRA1 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs755811625, COSV74142839; called by muse, mutect2, varscan2
- AL035078.4 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs749117053; called by muse, mutect2, varscan2
- ATP13A1 | c.1297G>C p.G433R | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99366716; called by muse, mutect2, varscan2
- BECN1 | c.10T>A p.S4T | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as COSV100831112; called by muse, mutect2, varscan2
- COL24A1 | c.3325C>A p.P1109T | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV65313975; called by muse, mutect2, varscan2
- FBLN1 | c.1225C>A p.R409S | Missense Mutation (SNP) | VAF 199/729 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1218807619; called by muse, mutect2, varscan2
- HIP1R | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53441598, COSV53442271; called by muse, mutect2, varscan2
- IQGAP3 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs749818611; called by muse, mutect2, varscan2
- KIAA1671 | c.2545G>A p.V849I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1273660436, COSV64450632; called by muse, mutect2, varscan2
- MAN2B2 | c.2999G>A p.R1000Q | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as rs757830667, COSV53450411, COSV99577991; called by muse, mutect2, varscan2
- MRC1 | c.3214G>A p.D1072N | Missense Mutation (SNP) | VAF 38/671 reads (6%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.462); catalogued as rs966584729; called by muse, mutect2
- PCDH7 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100688654; called by muse, mutect2, varscan2
- PRKG1 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773713867; called by muse, mutect2, varscan2
- PRPF40B | c.2053-4C>G | Splice Region (SNP) | VAF 29/155 reads (19%) | catalogued as rs1460701180; called by muse, mutect2, varscan2
- RABEP2 | c.555del p.H186Mfs*28 | Frame Shift Del (DEL) | VAF 23/108 reads (21%) | catalogued as COSV100706746; called by mutect2, pindel, varscan2
- SPON1 | c.1101C>A p.N367K | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782513392; called by muse, mutect2, varscan2
- UGT1A7 | c.671dup p.K225Qfs*9 | Frame Shift Ins (INS) | VAF 74/390 reads (19%) | catalogued as rs1476036720; called by pindel, varscan2
- VARS1 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763964925, COSV65155616; called by muse, mutect2, varscan2
- ZNF541 | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 94/441 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as COSV54545132; called by muse, mutect2, varscan2
- ACTR3C | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 74/207 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ANKDD1A | c.1425_1433del p.E475_S478delinsD | In Frame Del (DEL) | VAF 41/273 reads (15%) | called by mutect2, pindel, varscan2
- APBB3 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 53/266 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- BMP2K | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- C2CD3 | c.3044G>A p.G1015E | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNB2 | c.1042A>G p.R348G (on ENST00000324631 / NM_201596.3; = p.R293G on NM_000724.4) | Missense Mutation (SNP) | VAF 79/424 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CACNB2 | c.1043G>A p.R348K (on ENST00000324631 / NM_201596.3; = p.R293K on NM_000724.4) | Missense Mutation (SNP) | VAF 76/421 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- CAMKK1 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CAPS2 | c.1121del p.L374* | Frame Shift Del (DEL) | VAF 92/431 reads (21%) | called by mutect2, pindel, varscan2
- CC2D1B | c.1724C>A p.A575D | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CCDC168 | c.9328C>A p.H3110N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC96 | c.973_978del p.K325_E326del | In Frame Del (DEL) | VAF 19/111 reads (17%) | called by mutect2, pindel, varscan2
- CCL11 | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELF2 | c.1043C>G p.T348S (on ENST00000416382 / NM_001025077.3; = p.T355S on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/297 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CENPT | c.979C>A p.H327N | Missense Mutation (SNP) | VAF 88/393 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CLIP1 | c.2065G>T p.A689S (on ENST00000620786 / NM_001247997.1; = p.A678S on NM_002956.2) | Missense Mutation (SNP) | VAF 73/285 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL4A2 | c.2959A>T p.K987* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- CRELD1 | c.501_503delinsT p.Q168Vfs*2 | Frame Shift Del (DEL) | VAF 19/212 reads (9%) | called by pindel, varscan2*
- CSMD1 | c.2720G>T p.S907I (on ENST00000520002; = p.S906I on NM_033225.6) | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DGCR2 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNC1H1 | c.9835A>T p.K3279* | Nonsense Mutation (SNP) | VAF 70/380 reads (18%) | called by muse, mutect2
- ELP3 | c.1187T>A p.I396K | Missense Mutation (SNP) | VAF 62/246 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- EPHB3 | c.1496C>A p.S499Y | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.239); called by muse, mutect2
- ERMAP | c.1214del p.N405Tfs*5 | Frame Shift Del (DEL) | VAF 31/138 reads (22%) | called by mutect2, pindel, varscan2
- GOLGA8H | c.431A>G p.K144R | Missense Mutation (SNP) | VAF 211/898 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GRIN2D | c.651C>A p.H217Q | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- HDHD5 | c.637C>G p.L213V (on ENST00000336737 / NM_033070.3; = p.L183V on NM_017829.5) | Missense Mutation (SNP) | VAF 81/309 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- HIP1R | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KAT2A | c.2306T>C p.I769T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIN54 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC5B | c.7784C>A p.T2595N | Missense Mutation (SNP) | VAF 125/526 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- MYH3 | c.2963A>T p.E988V | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- MYH3 | c.2962G>T p.E988* | Nonsense Mutation (SNP) | VAF 40/187 reads (21%) | called by muse, mutect2, varscan2
- NELL2 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 56/259 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- NEO1 | c.1889C>T p.S630L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OPTN | c.49_51del p.S17del | In Frame Del (DEL) | VAF 58/352 reads (16%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1450A>T p.K484* | Nonsense Mutation (SNP) | VAF 39/108 reads (36%) | called by muse, mutect2, varscan2
- PCDHGA10 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 60/259 reads (23%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PDE8B | c.445T>C p.W149R | Missense Mutation (SNP) | VAF 96/292 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RAD50 | c.3817_3821del p.F1273Gfs*7 | Frame Shift Del (DEL) | VAF 55/243 reads (23%) | called by mutect2, pindel, varscan2
- RECK | c.945T>A p.N315K | Missense Mutation (SNP) | VAF 52/289 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RECK | c.1723A>T p.I575L | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROBO4 | c.2901C>G p.S967R | Missense Mutation (SNP) | VAF 23/274 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- SCAF4 | c.2341A>G p.I781V | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGCZ | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- SH3BP4 | c.2581G>A p.A861T | Missense Mutation (SNP) | VAF 22/289 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); called by muse, mutect2
- SLC35D2 | c.877del p.I293Ffs*5 | Frame Shift Del (DEL) | VAF 24/126 reads (19%) | called by mutect2, pindel, varscan2
- SPIN3 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 54/93 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNGAP1 | c.2786A>T p.N929I | Missense Mutation (SNP) | VAF 80/403 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TACR2 | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 79/331 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TASOR2 | c.3746del p.N1249Ifs*2 | Frame Shift Del (DEL) | VAF 45/201 reads (22%) | called by mutect2, pindel, varscan2
- TBC1D12 | c.1283_1291del p.A428_R431delinsG | In Frame Del (DEL) | VAF 29/169 reads (17%) | called by mutect2, pindel, varscan2
- THAP3 | c.381G>T p.M127I (on ENST00000054650 / NM_001195753.1; = p.M134I on NM_138350.3) | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- TMCO5A | c.383C>A p.T128K | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TOMM34 | c.795C>A p.Y265* | Nonsense Mutation (SNP) | VAF 47/164 reads (29%) | called by muse, mutect2, varscan2
- TTI2 | c.1139A>T p.H380L | Missense Mutation (SNP) | VAF 89/435 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC80 | c.1416G>A p.M472I | Missense Mutation (SNP) | VAF 99/438 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP28 | c.2470C>G p.R824G | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDFY3 | c.8669del p.F2890Sfs*14 | Frame Shift Del (DEL) | VAF 46/190 reads (24%) | called by mutect2, pindel, varscan2
- WIZ | c.4203G>T p.M1401I (on ENST00000673675 / NM_001371589.1; = p.M306I on NM_021241.3) | Missense Mutation (SNP) | VAF 62/352 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ZC3H7A | c.1892A>T p.Q631L | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- ZNF724 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- ANK2 | c.3555G>A p.E1185= | Silent (SNP) | VAF 28/259 reads (11%) | called by muse, mutect2, varscan2
- CAMKK1 | c.1509T>A p.A503= | Silent (SNP) | VAF 58/247 reads (23%) | called by muse, mutect2, varscan2
- CEP76 | c.1401A>T p.G467= | Silent (SNP) | VAF 51/255 reads (20%) | called by muse, mutect2, varscan2
- COL24A1 | c.3324T>C p.I1108= | Silent (SNP) | VAF 26/172 reads (15%) | called by muse, mutect2, varscan2
- DLX6 | c.751C>T p.L251= | Silent (SNP) | VAF 155/568 reads (27%) | catalogued as rs1225120437; called by muse, mutect2, varscan2
- DQX1 | c.1123C>A p.R375= | Silent (SNP) | VAF 52/219 reads (24%) | catalogued as rs150420269; called by muse, mutect2, varscan2
- DYNC1H1 | c.9837A>G p.K3279= | Silent (SNP) | VAF 67/372 reads (18%) | called by muse, mutect2
- DYRK1A | c.816A>G p.A272= | Silent (SNP) | VAF 65/354 reads (18%) | catalogued as COSV100117899; called by muse, mutect2, varscan2
- EPHB2 | c.1476G>A p.T492= | Silent (SNP) | VAF 117/452 reads (26%) | catalogued as rs370664820; called by muse, mutect2, varscan2
- FCGBP | c.4830G>T p.T1610= | Silent (SNP) | VAF 95/759 reads (13%) | called by muse, mutect2, varscan2
- ITGAD | c.1269C>T p.A423= | Silent (SNP) | VAF 35/220 reads (16%) | catalogued as COSV66760153; called by muse, mutect2, varscan2
- KAT6A | c.4482C>T p.V1494= | Silent (SNP) | VAF 32/156 reads (21%) | catalogued as COSV55904223; called by muse, mutect2, varscan2
- KCNH5 | c.1923C>T p.I641= | Silent (SNP) | VAF 54/190 reads (28%) | catalogued as COSV59768828; called by muse, mutect2, varscan2
- LRP1B | c.5394C>T p.A1798= | Silent (SNP) | VAF 72/342 reads (21%) | catalogued as rs754226036; called by muse, mutect2, varscan2
- OR4C6 | c.651G>T p.T217= | Silent (SNP) | VAF 83/354 reads (23%) | catalogued as rs776795154, COSV58605361, COSV58606268; called by muse, mutect2, varscan2
- PRMT7 | c.1095G>T p.V365= | Silent (SNP) | VAF 68/342 reads (20%) | called by muse, mutect2, varscan2
- SIKE1 | c.549A>G p.L183= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as rs963804130; called by muse, mutect2, varscan2
- STAC2 | c.150G>A p.E50= | Silent (SNP) | VAF 55/236 reads (23%) | called by muse, mutect2, varscan2
- TCFL5 | c.744T>C p.A248= | Silent (SNP) | VAF 24/119 reads (20%) | called by muse, mutect2, varscan2
- WTAP | c.996C>A p.L332= | Silent (SNP) | VAF 51/174 reads (29%) | called by muse, mutect2, varscan2
- ZBTB6 | c.627C>T p.D209= | Silent (SNP) | VAF 23/119 reads (19%) | called by muse, mutect2, varscan2
- ZNF616 | c.447T>A p.A149= | Silent (SNP) | VAF 46/213 reads (22%) | called by muse, mutect2, varscan2
- AOAH | c.*144A>G | 3'UTR (SNP) | VAF 8/248 reads (3%) | catalogued as rs879116316; called by muse, mutect2
- B4GALT4 | c.*325A>T | 3'UTR (SNP) | VAF 29/134 reads (22%) | called by muse, mutect2, varscan2
- CCT6A | c.-33A>G | 5'UTR (SNP) | VAF 46/207 reads (22%) | called by muse, mutect2, varscan2
- CFAP410 | c.643-236C>T | Intron (SNP) | VAF 53/236 reads (22%) | catalogued as rs748118167; called by muse, mutect2, varscan2
- FGFR3 | c.*755C>A | 3'UTR (SNP) | VAF 61/246 reads (25%) | called by muse, mutect2, varscan2
- FNTA | c.783-47del | Intron (DEL) | VAF 15/76 reads (20%) | called by mutect2, pindel, varscan2
- FSD1L | c.441+43dup | Intron (INS) | VAF 15/75 reads (20%) | called by mutect2, pindel
- IL12A | c.-25_-5del | 5'UTR (DEL) | VAF 45/286 reads (16%) | called by mutect2, pindel
- KIF1B | c.2115+5993G>T | Intron (SNP) | VAF 28/193 reads (15%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+5994A>G | Intron (SNP) | VAF 30/201 reads (15%) | catalogued as rs376929489; called by muse, mutect2, varscan2
- MALRD1 | c.5030-2396G>T | Intron (SNP) | VAF 52/200 reads (26%) | called by muse, mutect2, varscan2
- NBAS | c.3257+539T>A | Intron (SNP) | VAF 44/191 reads (23%) | called by muse, mutect2, varscan2
- RHOQ | c.202-15459_202-15446del | Intron (DEL) | VAF 25/145 reads (17%) | called by mutect2, pindel, varscan2
- SEPSECS | c.1211+37T>A | Intron (SNP) | VAF 75/249 reads (30%) | called by muse, mutect2, varscan2
